Somatic mutation profile of tumor specimen 0DEK1K from CCDI case PBBRAH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 1.5 years (531 days).
Specimen 0DEK1K: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51d1c492-e07e-4912-8f0a-4d58ca98a679.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DEJZN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe00eb1a-25c1-4835-af50-915a16f71e3c

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN9 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 116/430 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.699); catalogued as rs759944848, COSV55233430; called by muse, mutect2
- CD93 | c.857_863dup p.P289Lfs*10 | Frame Shift Ins (INS) | VAF 53/194 reads (27%) | called by mutect2, varscan2
